Gene-level copy-number profile of tumor specimen HCM-CSHL-0239-C18-01A from HCMI case HCM-CSHL-0239-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 55.0 years (20,072 days).
Specimen HCM-CSHL-0239-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9625a31d-505b-406b-9bb5-fe331f6e0d46.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0239-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/888071e1-9e6b-4ec9-b79b-0c24dc962671

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 922; copy number 2: 16,076; copy number 3: 34,093; copy number 4: 4,039; copy number 5: 898; copy number 6: 5; copy number 7: 776; copy number 8: 530; copy number 9: 1,032; copy number 10: 25.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr20:15,021,553–15,022,958, 2 genes (within-gene range 0–2): RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,363 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,549,089–145,066,685, 1,493 genes, copy number 7–10 (broad region; genes not listed).
- chr20:30,214,765–64,327,972, 870 genes, copy number 8–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 921. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
